Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6Z2, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6Z2-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with resection left retroperitoneal sarcoma.

Specimens Submitted:

1: SP: Left peritoneal tumor and kidney, resection

DIAGNOSIS:

1. SOFT TISSUE, LEFT RETROPERITONEAL TUMOR AND KIDNEY, RESECTION

- HIGH GRADE LEIOMYOSARCOMA.
- TUMOR MEASURES 7.2 CM GREATEST DIMENSION, INVOLVES RENAL VEIN AND PERIRENAL/RENAL HILAR FIBROADIPOSE TISSUE, SHOWS ABOUT 50% NECROSIS/HYALINIZATION, AND COMES WITHIN 0.1 CM OF UNDESIGNATED INKED MARGIN.
- KIDNEY SHOWS MARKED INTIMAL THICKENING OF INTERLOBULAR ARTERIES AND SCATTERED SCLEROTIC GLOMERULI.
- KIDNEY AND RENALVASCULAR MARGINS ARE FREE OF TUMOR.
- ONE BENIGN RENAL HILAR LYMPH NODE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "left retroperitoneal tumor and kidney" and consists of a kidney measuring 11.6 x 6.1 x 3.4 cm with attached fibroadipose tissue measuring 15.5 x 14.4 x 2.4 cm and an attached rubbery pink soft tissue mass measuring 7.2 x 6.1 x 4.9 cm. The ureter courses over the surface of the soft tissue mass and does not appear to be involved by tumor. A separate fragment of fibroadipose tissue is also submitted measuring 18 x 9.7 x 3.9 cm. The cut surface of the soft tissue mass reveals a lobulated pinkish yellow to red tissue. The tumor infiltrates the hilum

** Continued on next page **

ICD-O-3
Leiomyosarcoma NOS
8890/3
Site Retroperitoneum
CH870
JW 8/9/13

[page 2 of 2]
----- Page 2 of 2
of the kidney. The ureteral and vascular margins appear free of tumor. The cut surface of the kidney reveals unremarkable renal parenchyma and a cortical thickness of 0.6 cm. TPS is taken. Photographs are taken. Representatively submitted.

Summary of sections:

TK - tumor kidney interface
K - normal kidney
TC - tumor with overlying inked capsule
T - tumor
UVM - ureteral and vascular margins
BLN - bisected hilar lymph node
LN - candidate adipose tissue lymph node
F - fibroadipose tissue

Summary of Sections:

Part 1: SP: Left peritoneal tumor and kidney, resection

Block	Sect. Site	PCs
1	BLN	1
1	F	1
1	K	1
1	LN	1
6	T	6
3	TC	3
2	TK	2
1	UVM	1

** End of Report **

Criteria	kw 7/23/13	Yes	No
Local/Synchronous Primary	Noted		

Source: NCI Genomic Data Commons file 77d083fe-1b8e-4995-ba23-dcd935c75aaf (TCGA-DX-A6Z2.A4F3FC17-0642-48B5-BE53-FFD1BBBD0306.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).